Somatic mutation profile of tumor specimen C3L-02560-02 (aliquot CPT0128420006) from CPTAC case C3L-02560, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 73.2 years (26,748 days).
Specimen C3L-02560-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b339103-cbb4-400e-8be0-33b5c51134bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02560-31 (Blood Derived Normal), aliquot CPT0129440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b23e22b4-0444-40ad-b7ee-6346dc0c3935

The open-access MAF lists 50 somatic variants for this specimen: 38 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 6, Frame Shift Del 5, Nonsense Mutation 2, 3'UTR 2, 3'Flank 1, Frame Shift Ins 1, 5'Flank 1, Splice Site 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 37/194 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.2440C>T p.R814W | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs199473161, CM055530, COSV61129337, COSV61136044; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AHNAK | c.5209C>T p.P1737S | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs767487108; called by muse, mutect2
- BAP1 | c.125del p.P42Lfs*30 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | catalogued as COSV99963696; called by mutect2, pindel, varscan2
- C1orf112 | c.2164G>T p.G722* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99610079; called by muse, varscan2
- CCDC22 | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV66109115; called by muse, mutect2, varscan2
- CHERP | c.2134G>A p.G712S | Missense Mutation (SNP) | VAF 42/393 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99550188; called by muse, mutect2, varscan2
- DMXL1 | c.7618C>T p.R2540* | Nonsense Mutation (SNP) | VAF 112/371 reads (30%) | catalogued as rs903943796, COSV60718546; called by muse, mutect2, varscan2
- NPHS1 | c.2399G>A p.R800H | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.616); catalogued as rs146400394; called by muse, mutect2, varscan2
- P4HA2 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs769824324, COSV51326580; called by muse, mutect2, varscan2
- PADI3 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs146396025; called by muse, mutect2, varscan2
- POM121L2 | c.2728C>T p.P910S | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1350207902; called by muse, mutect2
- SOST | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 59/438 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs574411567, COSV57013139; called by muse, mutect2, varscan2
- SPG7 | c.1580G>T p.R527L (on ENST00000268704; = p.R534L on NM_003119.4) | Missense Mutation (SNP) | VAF 49/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51947737; called by muse, mutect2, varscan2
- ZNF124 | c.589G>A p.E197K (on ENST00000543802 / NM_001297568.1; = p.E135K on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as COSV61506753; called by muse, mutect2, varscan2
- AAAS | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- AKR1A1 | c.800del p.P267Lfs*20 | Frame Shift Del (DEL) | VAF 34/325 reads (10%) | called by mutect2, pindel, varscan2
- CYP2C19 | c.209del p.G70Afs*14 | Frame Shift Del (DEL) | VAF 17/171 reads (10%) | called by mutect2, pindel, varscan2
- DDX47 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 49/315 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM122C | c.74G>C p.R25T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); called by muse, mutect2
- HGF | c.1039A>C p.K347Q | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HGF | c.1038C>G p.C346W | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HTR6 | c.827T>A p.M276K | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- KIAA1210 | c.4477A>G p.K1493E | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- LAIR2 | c.56T>C p.I19T | Missense Mutation (SNP) | VAF 14/435 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); called by muse, mutect2
- MAPK14 | c.252del p.I84Mfs*22 | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- MDN1 | c.1536C>A p.H512Q | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC12 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.21); called by muse, mutect2, varscan2
- NPNT | c.322dup p.Y108Lfs*36 | Frame Shift Ins (INS) | VAF 23/177 reads (13%) | called by mutect2, pindel, varscan2
- OR2A12 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- PCBP1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PCDHA5 | c.74_77del p.A25Gfs*26 | Frame Shift Del (DEL) | VAF 53/275 reads (19%) | called by mutect2, pindel, varscan2
- PEX3 | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- PI4K2B | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.029); called by muse, mutect2
- SPEN | c.5206C>G p.P1736A | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- TANC1 | c.3857T>A p.I1286N | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2
- ZBTB2 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZC3H13 | c.117+1G>A p.X39_splice | Splice Site (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- AWAT2 | c.186C>A p.T62= | Silent (SNP) | VAF 12/122 reads (10%) | called by muse, varscan2
- BAHCC1 | c.3375G>A p.Q1125= | Silent (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- KCNH6 | c.411C>T p.A137= | Silent (SNP) | VAF 20/189 reads (11%) | catalogued as COSV100121204; called by muse, mutect2
- KLHL18 | c.669G>T p.L223= | Silent (SNP) | VAF 28/201 reads (14%) | called by muse, mutect2, varscan2
- PCDHB10 | c.2313A>G p.P771= | Silent (SNP) | VAF 50/265 reads (19%) | called by muse, mutect2, varscan2
- PNMA3 | c.1239C>T p.F413= | Silent (SNP) | VAF 30/234 reads (13%) | catalogued as COSV64721963; called by muse, mutect2, varscan2
- ARGLU1 | c.574-464G>A | Intron (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2, varscan2
- COLCA2 | chr11:111296376 C>T | 5'Flank (SNP) | VAF 17/209 reads (8%) | called by muse, mutect2
- CPLANE2 | chr1:16229009 del TTGT | 3'Flank (DEL) | VAF 15/80 reads (19%) | catalogued as rs1557556416; called by pindel, varscan2
- ERFE | c.*247G>A | 3'UTR (SNP) | VAF 53/357 reads (15%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.-52G>A | 5'UTR (SNP) | VAF 36/230 reads (16%) | catalogued as COSV100129442; called by mutect2, varscan2
- TMEM135 | c.*4054A>T | 3'UTR (SNP) | VAF 35/194 reads (18%) | called by muse, mutect2, varscan2
